Somatic mutation profile of tumor specimen TCGA-78-7633-01A (aliquot TCGA-78-7633-01A-11D-2063-08) from TCGA case TCGA-78-7633, project TCGA-LUAD (Lung Adenocarcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Adenocarcinoma with mixed subtypes; Tissue or organ of origin: Upper lobe, lung; AJCC pathologic stage: Stage IB; Age at diagnosis: 67.7 years (24,713 days).
Specimen TCGA-78-7633-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) a34b1b60-ae5a-46a4-b0a2-f6d2366e4f9b.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-78-7633-10A (Blood Derived Normal), aliquot TCGA-78-7633-10A-01D-2063-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/b7e50c64-0f35-4c1f-82cd-140b64b0b4b8

The open-access MAF lists 114 somatic variants for this specimen: 85 protein-altering or splice-affecting, 27 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 72, Silent 27, Nonsense Mutation 5, Frame Shift Del 3, RNA 2, Splice Site 2, Frame Shift Ins 1, Splice Region 1, In Frame Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- BRAF | c.1526G>T p.G509V (on ENST00000288602 / NM_001374244.1; = p.G469V on NM_004333.6 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 33/100 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs121913355, CM060876, COSV56061424, COSV56062352, COSV56065622; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- KEAP1 | c.997G>T p.G333C | Missense Mutation (SNP) | VAF 9/17 reads (53%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV50262468, COSV50595028; called by muse, mutect2, varscan2
- ABCA12 | c.6250T>A p.W2084R (on ENST00000272895 / NM_173076.3; = p.W1766R on NM_015657.3) | Missense Mutation (SNP) | VAF 52/119 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV55950052; called by muse, mutect2, varscan2
- ADAMTS14 | c.133A>T p.S45C | Missense Mutation (SNP) | VAF 30/77 reads (39%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.997); catalogued as COSV100941409; called by muse, mutect2, varscan2
- ADAMTS14 | c.134G>T p.S45I | Missense Mutation (SNP) | VAF 30/78 reads (38%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.983); catalogued as COSV100941411; called by muse, mutect2, varscan2
- ADCY10 | c.145T>G p.S49A | Missense Mutation (SNP) | VAF 18/123 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV63238681; called by muse, mutect2, varscan2
- ANKIB1 | c.973C>T p.P325S | Missense Mutation (SNP) | VAF 16/41 reads (39%) | SIFT deleterious (0.04); PolyPhen benign (0.003); catalogued as COSV56058762; called by muse, mutect2, varscan2
- ARHGAP15 | c.793C>G p.L265V | Missense Mutation (SNP) | VAF 100/183 reads (55%) | SIFT deleterious (0); PolyPhen benign (0.077); catalogued as COSV54479399, COSV99712075; called by muse, mutect2, varscan2
- ATAD2 | c.3854A>T p.E1285V | Missense Mutation (SNP) | VAF 12/34 reads (35%) | SIFT deleterious (0.04); PolyPhen benign (0.023); catalogued as COSV54877597; called by muse, varscan2
- ATP10D | c.143G>T p.G48V | Missense Mutation (SNP) | VAF 30/73 reads (41%) | SIFT deleterious (0.01); PolyPhen benign (0.231); catalogued as COSV56704090; called by muse, mutect2, varscan2
- BMPER | c.1927A>T p.I643F | Missense Mutation (SNP) | VAF 46/142 reads (32%) | SIFT deleterious (0.05); PolyPhen benign (0.031); catalogued as rs528093648, COSV51812126; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- BRAF | c.1525G>T p.G509* (on ENST00000288602 / NM_001374244.1; = p.G469* on NM_004333.6 and 3 other RefSeq transcripts) | Nonsense Mutation (SNP) | VAF 33/98 reads (34%) | catalogued as rs121913357, BM1457681, COSV56070557, COSV56082352, COSV99953015; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- BTN2A2 | c.205C>T p.R69W | Missense Mutation (SNP) | VAF 25/113 reads (22%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.95); catalogued as rs375285642; called by muse, mutect2, varscan2
- CAMKK1 | c.61G>T p.A21S | Missense Mutation (SNP) | VAF 11/43 reads (26%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.453); catalogued as COSV99340023; called by muse, mutect2, varscan2
- CCDC88C | c.3342G>T p.Q1114H | Missense Mutation (SNP) | VAF 6/33 reads (18%) | SIFT deleterious (0); PolyPhen benign (0.418); catalogued as COSV66234381; called by mutect2, varscan2
- CHD8 | c.797G>T p.G266V | Missense Mutation (SNP) | VAF 6/26 reads (23%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0.007); catalogued as COSV101303054; called by mutect2, varscan2
- CLCA2 | c.1810C>G p.P604A | Missense Mutation (SNP) | VAF 53/133 reads (40%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.983); catalogued as COSV65286191; called by muse, mutect2, varscan2
- CNTN2 | c.1180C>T p.Q394* | Nonsense Mutation (SNP) | VAF 21/119 reads (18%) | catalogued as COSV59348291; called by muse, mutect2, varscan2
- COL21A1 | c.1598G>T p.G533V | Missense Mutation (SNP) | VAF 8/23 reads (35%) | SIFT tolerated (0.08); PolyPhen probably damaging (1); catalogued as COSV55154177; called by muse, mutect2, varscan2
- CSF2RA | c.823G>T p.G275C | Missense Mutation (SNP) | VAF 41/114 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.921); catalogued as COSV62623628; called by muse, mutect2, varscan2
- CSMD3 | c.8432G>C p.R2811T (on ENST00000297405 / NM_001363185.1; = p.R2642T on NM_052900.3) | Missense Mutation (SNP) | VAF 21/64 reads (33%) | SIFT tolerated (0.13); PolyPhen benign (0.312); catalogued as rs754830554, COSV52108212; called by muse, mutect2, varscan2
- CSNK1A1L | c.893G>T p.W298L | Missense Mutation (SNP) | VAF 40/133 reads (30%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (1); catalogued as COSV65789354, COSV65789369; called by muse, mutect2, varscan2
- DSCAM | c.217C>A p.R73S | Missense Mutation (SNP) | VAF 23/80 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV68625338, COSV68626878; called by muse, mutect2, varscan2
- EVC2 | c.446G>T p.R149L | Missense Mutation (SNP) | VAF 21/74 reads (28%) | SIFT tolerated (0.2); PolyPhen benign (0); catalogued as COSV100185229, COSV60396249; called by muse, mutect2, varscan2
- FBF1 | c.2035C>T p.R679C (on ENST00000586717; = p.R693C on NM_001319193.1) | Missense Mutation (SNP) | VAF 25/43 reads (58%) | SIFT deleterious (0); PolyPhen probably damaging (0.961); catalogued as rs370224773; called by muse, mutect2, varscan2
- GABRG3 | c.937G>T p.V313L | Missense Mutation (SNP) | VAF 23/62 reads (37%) | SIFT tolerated (0.12); PolyPhen benign (0.445); catalogued as COSV100409200, COSV61510790; called by muse, mutect2, varscan2
- GBP4 | c.1909G>A p.G637S | Missense Mutation (SNP) | VAF 30/87 reads (34%) | SIFT tolerated, low confidence (1); PolyPhen benign (0.009); catalogued as COSV63252993; called by muse, varscan2
- GDPD2 | c.814G>C p.D272H | Missense Mutation (SNP) | VAF 10/19 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100978649, COSV65532037; called by muse, mutect2, varscan2
- HSD3B7 | c.238G>A p.A80T | Missense Mutation (SNP) | VAF 4/24 reads (17%) | SIFT tolerated (0.07); PolyPhen benign (0.019); catalogued as rs1328595676, COSV52679672; called by muse, mutect2, varscan2
- IFT172 | c.1090G>A p.G364R | Missense Mutation (SNP) | VAF 81/292 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.577); catalogued as COSV53130047; called by muse, mutect2, varscan2
- IKZF2 | c.1470G>T p.M490I | Missense Mutation (SNP) | VAF 110/196 reads (56%) | SIFT deleterious (0); PolyPhen possibly damaging (0.53); catalogued as COSV59576689; called by muse, mutect2, varscan2
- IQGAP2 | c.303+1G>A p.X101_splice | Splice Site (SNP) | VAF 62/118 reads (53%) | catalogued as rs1200135112, COSV57168319; called by muse, mutect2, varscan2
- JPH3 | c.441C>G p.S147R | Missense Mutation (SNP) | VAF 25/73 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs140115944, COSV52464450; called by muse, mutect2, varscan2
- KANK4 | c.2587A>G p.M863V | Missense Mutation (SNP) | VAF 46/118 reads (39%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as rs755326990, COSV58092044; called by muse, mutect2, varscan2
- KCNK6 | c.262G>A p.D88N | Missense Mutation (SNP) | VAF 6/20 reads (30%) | SIFT tolerated (0.24); PolyPhen benign (0.007); catalogued as COSV99649284; called by muse, mutect2, varscan2
- KDM5D | c.3052G>C p.A1018P | Missense Mutation (SNP) | VAF 24/36 reads (67%) | SIFT tolerated (0.12); PolyPhen probably damaging (1); catalogued as COSV58736046; called by muse, mutect2, varscan2
- KRT83 | c.753G>T p.E251D | Missense Mutation (SNP) | VAF 25/88 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.9); catalogued as COSV53338549; called by muse, mutect2, varscan2
- KRTAP13-1 | c.404G>C p.C135S | Missense Mutation (SNP) | VAF 15/53 reads (28%) | SIFT tolerated (0.5); PolyPhen benign (0.028); catalogued as COSV62662859; called by muse, mutect2, varscan2
- KRTAP19-5 | c.106G>T p.G36C | Missense Mutation (SNP) | VAF 64/188 reads (34%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (1); catalogued as COSV61858230; called by muse, mutect2, varscan2
- LPAR3 | c.598C>G p.L200V | Missense Mutation (SNP) | VAF 26/61 reads (43%) | SIFT tolerated (0.56); PolyPhen benign (0.003); catalogued as COSV65452727; called by muse, mutect2, varscan2
- MYH2 | c.5044C>A p.R1682S | Missense Mutation (SNP) | VAF 23/69 reads (33%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV104393337, COSV55432102, COSV99819620; called by muse, mutect2, varscan2
- NCEH1 | c.671G>T p.R224I (on ENST00000538775; = p.R184I on NM_020792.6 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 43/138 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV56432920, COSV56435265; called by muse, mutect2, varscan2
- NCKAP1L | c.787G>A p.G263R | Missense Mutation (SNP) | VAF 39/106 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53203481; called by muse, mutect2, varscan2
- NCR1 | c.108T>A p.H36Q | Missense Mutation (SNP) | VAF 26/97 reads (27%) | SIFT deleterious (0.01); PolyPhen benign (0.049); catalogued as COSV52555471; called by muse, mutect2, varscan2
- NFIX | c.383G>T p.R128L | Missense Mutation (SNP) | VAF 22/33 reads (67%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV100666411, COSV62175630; called by muse, mutect2, varscan2
- NKX2-5 | c.656C>A p.A219E | Missense Mutation (SNP) | VAF 7/19 reads (37%) | SIFT deleterious (0); PolyPhen possibly damaging (0.9); catalogued as CM013527, COSV100234739; called by muse, mutect2, varscan2
- OR11H1 | c.560C>A p.P187Q | Missense Mutation (SNP) | VAF 30/65 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as COSV99421617; called by mutect2, varscan2
- OR2D3 | c.18G>T p.L6F | Missense Mutation (SNP) | VAF 24/74 reads (32%) | SIFT tolerated, low confidence (0.3); PolyPhen benign (0); catalogued as COSV58572509; called by muse, mutect2, varscan2
- OR4C15 | c.229G>T p.E77* (on ENST00000314644; = p.E23* on NM_001001920.2) | Nonsense Mutation (SNP) | VAF 61/150 reads (41%) | catalogued as rs765377925, COSV58951205, COSV58952974; called by muse, mutect2, varscan2
- OR51B2 | c.722C>G p.S241C | Missense Mutation (SNP) | VAF 23/69 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV60915966, COSV60916216; called by muse, mutect2, varscan2
- OR5T3 | c.776G>T p.G259V | Missense Mutation (SNP) | VAF 57/156 reads (37%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.612); catalogued as COSV57379481; called by muse, mutect2, varscan2
- OR6K3 | c.445C>A p.Q149K (on ENST00000368146; = p.Q133K on NM_001005327.2) | Missense Mutation (SNP) | VAF 30/162 reads (19%) | SIFT deleterious (0); PolyPhen benign (0.041); catalogued as COSV63745300; called by muse, mutect2, varscan2
- PCDH10 | c.124G>T p.G42C | Missense Mutation (SNP) | VAF 34/131 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52087941; called by muse, mutect2, varscan2
- PCDH17 | c.2413C>A p.P805T | Missense Mutation (SNP) | VAF 6/22 reads (27%) | SIFT tolerated (1); PolyPhen possibly damaging (0.758); catalogued as COSV64971913; called by muse, mutect2, varscan2
- PDE2A | c.2111A>G p.N704S | Missense Mutation (SNP) | VAF 19/54 reads (35%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.697); catalogued as rs1325878042, COSV57802698; called by muse, mutect2, varscan2
- PDZD2 | c.2213G>A p.G738E | Missense Mutation (SNP) | VAF 17/57 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56851429, COSV56862920; called by muse, mutect2, varscan2
- PRR12 | c.1756G>A p.D586N (on ENST00000615927; = p.D1407N on NM_020719.3) | Missense Mutation (SNP) | VAF 44/126 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV69816663; called by muse, mutect2, varscan2
- PSD2 | c.611C>T p.A204V | Missense Mutation (SNP) | VAF 31/68 reads (46%) | SIFT tolerated (0.07); PolyPhen benign (0); catalogued as rs764425844, COSV51197172; called by muse, mutect2, varscan2
- PSKH2 | c.1033T>A p.S345T | Missense Mutation (SNP) | VAF 37/99 reads (37%) | SIFT deleterious (0.01); PolyPhen benign (0.111); catalogued as COSV52609292; called by muse, mutect2, varscan2
- PSMD12 | c.1308G>A p.M436I | Missense Mutation (SNP) | VAF 27/111 reads (24%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.824); catalogued as COSV62065157; called by muse, mutect2, varscan2
- RBMS1 | c.939T>G p.I313M | Missense Mutation (SNP) | VAF 59/129 reads (46%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.458); catalogued as COSV62350614; called by muse, mutect2, varscan2
- RNPC3 | c.1391G>T p.R464L | Missense Mutation (SNP) | VAF 19/62 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV63714103; called by muse, mutect2, varscan2
- RYR1 | c.3673T>C p.F1225L | Missense Mutation (SNP) | VAF 54/154 reads (35%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.97); catalogued as COSV62089682; called by muse, mutect2, varscan2
- SDR16C5 | c.103C>T p.R35W | Missense Mutation (SNP) | VAF 26/75 reads (35%) | SIFT deleterious (0); PolyPhen possibly damaging (0.656); catalogued as rs116944947; called by muse, mutect2, varscan2
- SLIT3 | c.4256A>G p.H1419R | Missense Mutation (SNP) | VAF 16/61 reads (26%) | SIFT tolerated (0.11); PolyPhen benign (0.045); catalogued as COSV60593763; called by muse, mutect2, varscan2
- SMAD3 | c.748G>T p.A250S | Missense Mutation (SNP) | VAF 13/45 reads (29%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.967); catalogued as COSV59280523, COSV59280801; called by muse, mutect2, varscan2
- SMC4 | c.2708A>T p.Q903L | Missense Mutation (SNP) | VAF 31/73 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as COSV61003170; called by muse, mutect2, varscan2
- SORCS3 | c.2413C>G p.L805V | Missense Mutation (SNP) | VAF 27/71 reads (38%) | SIFT tolerated (1); PolyPhen benign (0.01); catalogued as COSV63793517, COSV63799137; called by muse, varscan2
- SP100 | c.2052+1G>T p.X684_splice | Splice Site (SNP) | VAF 36/86 reads (42%) | catalogued as COSV50974752; called by muse, mutect2, varscan2
- SPTBN5 | c.3852G>T p.T1284= | Splice Region (SNP) | VAF 8/12 reads (67%) | catalogued as COSV58016778; called by muse, mutect2, varscan2
- TLR4 | c.280G>T p.E94* (on ENST00000355622 / NM_138554.5; = p.E54* on NM_003266.4) | Nonsense Mutation (SNP) | VAF 14/45 reads (31%) | catalogued as COSV100790693, COSV62922466; called by muse, mutect2, varscan2
- TRPA1 | c.2086G>C p.E696Q | Missense Mutation (SNP) | VAF 33/97 reads (34%) | SIFT deleterious (0); PolyPhen possibly damaging (0.846); catalogued as COSV51555777, COSV51559719; called by muse, mutect2, varscan2
- TSKS | c.5C>A p.A2E | Missense Mutation (SNP) | VAF 14/66 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as CM142651, COSV55873089, COSV55877298; called by muse, mutect2, varscan2
- USP21 | c.259G>A p.G87R | Missense Mutation (SNP) | VAF 43/81 reads (53%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.854); catalogued as COSV57086864; called by muse, mutect2, varscan2
- VN1R4 | c.30G>T p.M10I | Missense Mutation (SNP) | VAF 25/86 reads (29%) | SIFT tolerated (0.58); PolyPhen benign (0.013); catalogued as COSV60804666, COSV60805487; called by muse, mutect2, varscan2
- WDR7 | c.4241A>G p.N1414S | Missense Mutation (SNP) | VAF 34/102 reads (33%) | SIFT tolerated (0.42); PolyPhen benign (0.137); catalogued as COSV54348548; called by muse, mutect2, varscan2
- ZBTB1 | c.1711G>C p.E571Q | Missense Mutation (SNP) | VAF 54/145 reads (37%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.986); catalogued as rs1056236881, COSV62437324; called by muse, mutect2, varscan2
- ZNF277 | c.931G>A p.A311T | Missense Mutation (SNP) | VAF 24/96 reads (25%) | SIFT tolerated (0.43); PolyPhen benign (0.036); catalogued as COSV62463285; called by muse, mutect2, varscan2
- ZNF479 | c.25G>T p.G9* | Nonsense Mutation (SNP) | VAF 27/76 reads (36%) | catalogued as COSV58636062; called by muse, mutect2, varscan2
- ZNF536 | c.2213C>A p.P738Q | Missense Mutation (SNP) | VAF 50/147 reads (34%) | SIFT tolerated (0.1); PolyPhen benign (0.007); catalogued as COSV62819024; called by muse, mutect2, varscan2
- ELL3 | c.1009_1017del p.V338_R340del | In Frame Del (DEL) | VAF 15/57 reads (26%) | called by mutect2, pindel, varscan2
- NSUN7 | c.1016dup p.T340Hfs*6 | Frame Shift Ins (INS) | VAF 28/104 reads (27%) | called by mutect2, pindel, varscan2
- UBA6 | c.1831del p.Y611Tfs*17 | Frame Shift Del (DEL) | VAF 23/58 reads (40%) | called by mutect2, pindel, varscan2
- XKR4 | c.1840del p.R614Efs*8 | Frame Shift Del (DEL) | VAF 26/89 reads (29%) | called by mutect2, pindel, varscan2
- ZMYM1 | c.1416del p.D473Mfs*48 | Frame Shift Del (DEL) | VAF 6/70 reads (9%) | called by mutect2, pindel
- AC092143.1 | c.1956G>T p.P652= | Silent (SNP) | VAF 36/119 reads (30%) | catalogued as COSV59247109; called by muse, mutect2, varscan2
- AIM2 | c.492C>A p.P164= | Silent (SNP) | VAF 122/208 reads (59%) | catalogued as COSV63698346; called by muse, mutect2, varscan2
- AL645922.1 | c.1623G>C p.L541= | Silent (SNP) | VAF 16/87 reads (18%) | catalogued as COSV54959373; called by muse, mutect2, varscan2
- ANK3 | c.1983C>T p.T661= | Silent (SNP) | VAF 30/83 reads (36%) | catalogued as COSV55045262; called by muse, mutect2, varscan2
- ATP10A | c.4431A>G p.S1477= | Silent (SNP) | VAF 23/71 reads (32%) | catalogued as COSV63513849; called by muse, mutect2, varscan2
- CAMKK1 | c.60G>T p.V20= | Silent (SNP) | VAF 11/44 reads (25%) | catalogued as COSV99340031; called by muse, mutect2, varscan2
- FCRL2 | c.114C>T p.C38= | Silent (SNP) | VAF 14/85 reads (16%) | catalogued as COSV63832621; called by muse, mutect2, varscan2
- FRMD4A | c.1032G>T p.T344= | Silent (SNP) | VAF 38/79 reads (48%) | catalogued as COSV52715388; called by muse, mutect2, varscan2
- HARS2 | c.1143G>T p.V381= | Silent (SNP) | VAF 12/78 reads (15%) | catalogued as COSV51226805; called by muse, mutect2, varscan2
- KCNK16 | c.534G>C p.L178= | Silent (SNP) | VAF 33/147 reads (22%) | catalogued as COSV64677256; called by muse, mutect2, varscan2
- KCNT2 | c.1449A>G p.R483= | Silent (SNP) | VAF 74/128 reads (58%) | catalogued as COSV54065181; called by muse, mutect2, varscan2
- MRPL50 | c.108A>G p.P36= | Silent (SNP) | VAF 40/88 reads (45%) | catalogued as rs917039498, COSV66405968; called by muse, mutect2, varscan2
- MUC16 | c.1347C>A p.S449= | Silent (SNP) | VAF 54/89 reads (61%) | catalogued as rs200301454, COSV67446794; called by muse, mutect2, varscan2
- MYOCD | c.1743T>C p.F581= | Silent (SNP) | VAF 30/90 reads (33%) | catalogued as COSV58497622; called by muse, mutect2, varscan2
- NGF | c.297C>T p.D99= | Silent (SNP) | VAF 13/40 reads (33%) | catalogued as COSV65686899; called by muse, mutect2, varscan2
- OR10K1 | c.663C>A p.I221= | Silent (SNP) | VAF 46/192 reads (24%) | catalogued as rs151132888, COSV56870663, COSV56872137; called by muse, mutect2, varscan2
- OR5T2 | c.795G>A p.L265= | Silent (SNP) | VAF 52/142 reads (37%) | catalogued as rs756795146, COSV57587912; called by muse, mutect2, varscan2
- PCDHA3 | c.2214G>T p.T738= | Silent (SNP) | VAF 42/178 reads (24%) | catalogued as rs782062306, COSV63539107; called by muse, mutect2, varscan2
- PRAMEF14 | c.540G>A p.L180= | Silent (SNP) | VAF 170/499 reads (34%) | called by muse, mutect2, varscan2
- RUNDC3B | c.762C>A p.V254= | Silent (SNP) | VAF 12/33 reads (36%) | catalogued as COSV100406837; called by muse, mutect2, varscan2
- SLC7A8 | c.1248C>T p.I416= | Silent (SNP) | VAF 46/123 reads (37%) | catalogued as rs753488263, COSV57552902; called by muse, varscan2
- TCF20 | c.5685C>A p.A1895= | Silent (SNP) | VAF 53/143 reads (37%) | catalogued as COSV59488603; called by muse, mutect2, varscan2
- TMEM150B | c.123C>T p.Y41= | Silent (SNP) | VAF 39/113 reads (35%) | catalogued as COSV58593175; called by muse, mutect2, varscan2
- TPH1 | c.678T>A p.G226= | Silent (SNP) | VAF 25/58 reads (43%) | catalogued as COSV51456887; called by muse, mutect2, varscan2
- TRAV14DV4 | c.135T>C p.Y45= | Silent (SNP) | VAF 34/88 reads (39%) | called by muse, mutect2, varscan2
- TRRAP | c.4368A>G p.P1456= | Silent (SNP) | VAF 17/41 reads (41%) | catalogued as COSV62839400; called by muse, mutect2, varscan2
- ZIC4 | c.828G>T p.T276= | Silent (SNP) | VAF 8/37 reads (22%) | catalogued as COSV67170739; called by muse, mutect2, varscan2
- AL163540.1 | n.300G>T | RNA (SNP) | VAF 70/140 reads (50%) | called by muse, mutect2, varscan2
- OR2W5 | n.499G>A | RNA (SNP) | VAF 47/81 reads (58%) | called by muse, mutect2, varscan2
